Somatic mutation profile of tumor specimen C3L-08230-04 (aliquot CPT0486350006) from CPTAC case C3L-08230, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 86.5 years (31,597 days).
Specimen C3L-08230-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dbd7c2e0-8939-41f4-b64c-9fc8f9664417.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08230-31 (Blood Derived Normal), aliquot CPT0486470003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56e1c4a7-d923-4e51-b293-de479a7f8054

The open-access MAF lists 153 somatic variants for this specimen: 113 protein-altering or splice-affecting, 35 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 100, Silent 35, Nonsense Mutation 9, Frame Shift Del 3, 5'Flank 3, Intron 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.581T>G p.L194R | Missense Mutation (SNP) | VAF 115/191 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519998, COSV52663681, COSV52677924, COSV52679257, COSV52713187; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ACTR8 | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 63/316 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.703); catalogued as rs753279053; called by muse, mutect2, varscan2
- ADAM29 | c.1466A>T p.E489V | Missense Mutation (SNP) | VAF 52/212 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.044); catalogued as rs753736925, COSV63668071; called by muse, mutect2, varscan2
- ANXA11 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 85/446 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as COSV55415457; called by muse, mutect2, varscan2
- APCDD1L | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 77/517 reads (15%) | catalogued as COSV100954068, COSV64486439; called by muse, mutect2, varscan2
- ARL14EPL | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs775426527, COSV74124120; called by muse, mutect2, varscan2
- ATL2 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 62/286 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.647); catalogued as rs752466538; called by muse, mutect2, varscan2
- ATRNL1 | c.3631T>G p.F1211V | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58094324; called by muse, mutect2, varscan2
- BMS1 | c.627A>C p.E209D | Missense Mutation (SNP) | VAF 76/242 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV65734339; called by muse, mutect2, varscan2
- CCDC105 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 106/317 reads (33%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.602); catalogued as rs1486313382; called by muse, mutect2, varscan2
- CCDC63 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 62/262 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs775890946, COSV57531110; called by muse, mutect2, varscan2
- CFAP58 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 45/228 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as rs200132388, COSV57212082, COSV57213757; called by muse, mutect2, varscan2
- CLCN4 | c.2080C>T p.R694W | Missense Mutation (SNP) | VAF 100/456 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs774722248, COSV66469177; called by muse, mutect2, varscan2
- DNER | c.1662C>G p.N554K | Missense Mutation (SNP) | VAF 57/277 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as COSV59163503; called by muse, mutect2, varscan2
- EYA2 | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 40/319 reads (13%) | catalogued as COSV57938541; called by muse, mutect2, varscan2
- FGFR2 | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 80/319 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1171095092, COSV60644157; called by muse, mutect2, varscan2
- FOXD4L4 | c.50T>C p.L17P | Missense Mutation (SNP) | VAF 50/568 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.675); catalogued as rs1255269818; called by muse, mutect2
- GARRE1 | c.3085G>A p.A1029T | Missense Mutation (SNP) | VAF 124/432 reads (29%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as rs372487392; called by muse, mutect2
- GMEB2 | c.1468G>A p.V490M | Missense Mutation (SNP) | VAF 102/617 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs566776788; called by muse, mutect2, varscan2
- GRN | c.68G>A p.G23D | Missense Mutation (SNP) | VAF 89/313 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs1322702054; called by muse, mutect2, varscan2
- HUWE1 | c.8986C>T p.R2996W | Missense Mutation (SNP) | VAF 114/497 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53346582; called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.317G>A p.R106K | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.105); catalogued as rs745732603; called by muse, mutect2, varscan2
- KDM4D | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 88/341 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1194892240, COSV58634703; called by muse, mutect2, varscan2
- LRCH1 | c.1414A>G p.I472V | Missense Mutation (SNP) | VAF 38/181 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs761120928; called by muse, mutect2, varscan2
- MAGEB5 | c.297A>C p.E99D | Missense Mutation (SNP) | VAF 75/317 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as rs1170322916, COSV66868659; called by muse, mutect2, varscan2
- MAPK14 | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 35/218 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758211646, COSV57695720; called by muse, mutect2, varscan2
- MARCHF4 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 86/350 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.766); catalogued as rs1255717251, COSV56102500; called by muse, mutect2, varscan2
- MGAT4A | c.115C>T p.R39* | Nonsense Mutation (SNP) | VAF 37/192 reads (19%) | catalogued as rs141026005; called by muse, mutect2, varscan2
- MPP5 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as rs991445460, COSV99906856; called by muse, mutect2, varscan2
- NPTX2 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 97/545 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs1486223038, COSV99674822; called by muse, mutect2, varscan2
- NPTX2 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 129/424 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs563276077, COSV99675175; called by muse, mutect2, varscan2
- OR4C15 | c.379T>C p.S127P (on ENST00000314644; = p.S73P on NM_001001920.2) | Missense Mutation (SNP) | VAF 88/337 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV58951546, COSV58952166; called by muse, mutect2, varscan2
- OR4C6 | c.89T>G p.L30R | Missense Mutation (SNP) | VAF 64/249 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV58604284, COSV58604819; called by muse, mutect2, varscan2
- OR5H8 | c.687del p.V230Sfs*81 | Frame Shift Del (DEL) | VAF 29/98 reads (30%) | catalogued as rs553513516; called by mutect2, varscan2
- PLIN3 | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 79/292 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as rs368870755; called by muse, mutect2, varscan2
- POLR1B | c.518A>G p.N173S | Missense Mutation (SNP) | VAF 34/223 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs745546863; called by muse, mutect2, varscan2
- PRKD1 | c.2413T>G p.W805G | Missense Mutation (SNP) | VAF 48/225 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59583233; called by muse, mutect2, varscan2
- QPCTL | c.43G>T p.E15* | Nonsense Mutation (SNP) | VAF 85/261 reads (33%) | catalogued as COSV50004417; called by muse, mutect2, varscan2
- RASGRP2 | c.247A>C p.I83L | Missense Mutation (SNP) | VAF 60/242 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.336); catalogued as rs373984261; called by muse, mutect2, varscan2
- SHANK2 | c.4459G>A p.A1487T | Missense Mutation (SNP) | VAF 140/350 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs546725564; called by muse, mutect2, varscan2
- SHISA6 | c.1193C>T p.T398M (on ENST00000409168 / NM_001173461.1; = p.T449M on NM_207386.4) | Missense Mutation (SNP) | VAF 91/296 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.215); catalogued as rs760800852; called by muse, mutect2, varscan2
- SLC12A7 | c.3187G>A p.E1063K | Missense Mutation (SNP) | VAF 77/343 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as rs1419123788, COSV53756590; called by muse, mutect2, varscan2
- SLC25A2 | c.235T>C p.S79P | Missense Mutation (SNP) | VAF 67/223 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99508291, COSV99508398; called by muse, mutect2, varscan2
- SLC8A3 | c.1480C>T p.P494S | Missense Mutation (SNP) | VAF 157/269 reads (58%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs1359479094; called by muse, mutect2, varscan2
- SPATA18 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs139000378, COSV99731515; called by muse, mutect2, varscan2
- SPPL2B | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 66/241 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as rs139004876; called by muse, mutect2, varscan2
- STRIP2 | c.1988C>T p.S663F | Missense Mutation (SNP) | VAF 117/343 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50803445; called by muse, mutect2, varscan2
- TBX2 | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 125/371 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs758477912; called by muse, mutect2, varscan2
- TENT5D | c.631T>A p.F211I | Missense Mutation (SNP) | VAF 46/345 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100382787; called by muse, mutect2, varscan2
- TNIK | c.1931C>T p.S644L | Missense Mutation (SNP) | VAF 80/293 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs753125107, COSV52680123; called by muse, mutect2, varscan2
- VSTM4 | c.632G>T p.R211I | Missense Mutation (SNP) | VAF 43/299 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV100252160; called by muse, mutect2, varscan2
- AKAP13 | c.4704del p.N1571Mfs*8 | Frame Shift Del (DEL) | VAF 32/178 reads (18%) | called by mutect2, pindel, varscan2
- AL592490.1 | c.1808A>T p.E603V | Missense Mutation (SNP) | VAF 59/342 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- ATP11C | c.2180A>T p.K727M | Missense Mutation (SNP) | VAF 60/256 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- BMP10 | c.504T>A p.F168L | Missense Mutation (SNP) | VAF 53/273 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- CCDC102B | c.992T>C p.I331T | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CCL20 | c.208_209del p.K70Vfs*21 | Frame Shift Del (DEL) | VAF 45/200 reads (23%) | called by mutect2, pindel, varscan2
- CCNP | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 83/323 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CEP85L | c.442A>T p.K148* | Nonsense Mutation (SNP) | VAF 71/302 reads (24%) | called by muse, mutect2, varscan2
- CHCHD6 | c.428G>A p.S143N | Missense Mutation (SNP) | VAF 48/204 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CHD8 | c.2742C>G p.I914M (on ENST00000646647 / NM_001170629.2; = p.I635M on NM_020920.4) | Missense Mutation (SNP) | VAF 56/272 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- COL11A1 | c.3717A>C p.Q1239H | Missense Mutation (SNP) | VAF 59/182 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- COL4A5 | c.1312G>A p.G438S | Missense Mutation (SNP) | VAF 79/345 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- COL4A5 | c.4417G>A p.A1473T | Missense Mutation (SNP) | VAF 82/415 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- COX4I2 | c.245_247+7del p.X82_splice | Splice Site (DEL) | VAF 70/288 reads (24%) | called by mutect2, pindel, varscan2
- CSMD1 | c.4851A>C p.Q1617H (on ENST00000520002; = p.Q1616H on NM_033225.6) | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- DIP2C | c.925C>A p.Q309K | Missense Mutation (SNP) | VAF 80/469 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- DMD | c.7856A>C p.K2619T | Missense Mutation (SNP) | VAF 46/235 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- DNAH3 | c.8785C>A p.L2929M | Missense Mutation (SNP) | VAF 75/355 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK11 | c.5417A>C p.K1806T | Missense Mutation (SNP) | VAF 46/240 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPB41L2 | c.220A>G p.I74V | Missense Mutation (SNP) | VAF 74/374 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- EYS | c.3176T>C p.L1059P | Missense Mutation (SNP) | VAF 42/193 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABRA5 | c.380A>G p.K127R | Missense Mutation (SNP) | VAF 73/258 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- GLI3 | c.1398C>A p.D466E | Missense Mutation (SNP) | VAF 80/318 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GPRASP2 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 70/360 reads (19%) | called by muse, mutect2, varscan2
- ICE1 | c.129A>T p.K43N | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IL12RB2 | c.2271A>T p.Q757H | Missense Mutation (SNP) | VAF 92/316 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- KRT14 | c.638G>A p.S213N | Missense Mutation (SNP) | VAF 89/152 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- LAMA4 | c.2686G>A p.G896S (on ENST00000230538 / NM_001105206.3; = p.G889S on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- MAGEB16 | c.422A>C p.K141T | Missense Mutation (SNP) | VAF 68/374 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.065); called by muse, mutect2
- MARCHF4 | c.964G>T p.D322Y | Missense Mutation (SNP) | VAF 63/302 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MEGF10 | c.1771G>T p.A591S | Missense Mutation (SNP) | VAF 68/256 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- MYO5A | c.1621C>G p.P541A | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by mutect2, varscan2
- NCAPD3 | c.2534C>G p.T845R | Missense Mutation (SNP) | VAF 40/233 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OLFM1 | c.364C>A p.L122I | Missense Mutation (SNP) | VAF 72/264 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.844); called by muse, varscan2
- OR7G2 | c.62G>A p.S21N | Missense Mutation (SNP) | VAF 23/290 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- OR9A2 | c.821T>G p.V274G | Missense Mutation (SNP) | VAF 88/442 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- PCDHB11 | c.292T>C p.S98P | Missense Mutation (SNP) | VAF 71/254 reads (28%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHGA7 | c.1585C>A p.Q529K | Missense Mutation (SNP) | VAF 80/252 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- POU4F1 | c.574C>T p.H192Y | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.528); called by muse, varscan2
- RAB11FIP1 | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 100/260 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- RPS18 | c.56A>G p.N19S | Missense Mutation (SNP) | VAF 76/361 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- RTP1 | c.33C>A p.C11* | Nonsense Mutation (SNP) | VAF 14/246 reads (6%) | called by muse, mutect2
- SLC12A5 | c.2450T>C p.L817P (on ENST00000454036 / NM_001134771.2; = p.L794P on NM_020708.5) | Missense Mutation (SNP) | VAF 48/307 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC36A4 | c.1049C>G p.S350* | Nonsense Mutation (SNP) | VAF 31/118 reads (26%) | called by muse, mutect2, varscan2
- SLCO1A2 | c.1564T>G p.F522V | Missense Mutation (SNP) | VAF 119/249 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- SMYD1 | c.848T>G p.L283R | Missense Mutation (SNP) | VAF 64/299 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- SNUPN | c.602C>G p.T201S | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- SP8 | c.1047C>A p.S349R (on ENST00000361443 / NM_198956.4; = p.S367R on NM_182700.6) | Missense Mutation (SNP) | VAF 74/598 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); called by muse, varscan2
- SPATA31D1 | c.2407A>G p.R803G | Missense Mutation (SNP) | VAF 70/248 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- TMEM151B | c.1610C>T p.P537L | Missense Mutation (SNP) | VAF 93/378 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.21554C>A p.S7185Y (on ENST00000591111; = p.S6258Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/212 reads (20%) | PolyPhen benign (0.422); called by muse, mutect2, varscan2
- TUBB1 | c.960G>T p.K320N | Missense Mutation (SNP) | VAF 140/451 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- UBXN11 | c.530G>A p.W177* (on ENST00000374221 / NM_183008.2; = p.W144* on NM_145345.2) | Nonsense Mutation (SNP) | VAF 96/175 reads (55%) | called by muse, mutect2, varscan2
- WDFY4 | c.8711C>A p.T2904N | Missense Mutation (SNP) | VAF 74/369 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- XRN1 | c.2570G>A p.S857N | Missense Mutation (SNP) | VAF 47/303 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- ZFHX2 | c.3166A>G p.K1056E | Missense Mutation (SNP) | VAF 127/252 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ZFHX4 | c.2837A>C p.K946T | Missense Mutation (SNP) | VAF 69/334 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF728 | c.1484T>C p.L495P | Missense Mutation (SNP) | VAF 63/222 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF804B | c.266A>C p.K89T | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF808 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 53/217 reads (24%) | SIFT tolerated (0.97); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ZNF831 | c.4850T>C p.V1617A | Missense Mutation (SNP) | VAF 200/438 reads (46%) | SIFT tolerated (0.8); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF879 | c.296A>G p.E99G | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- APCDD1L | c.564G>A p.A188= | Silent (SNP) | VAF 97/628 reads (15%) | called by muse, mutect2, varscan2
- CCT5 | c.1557T>A p.L519= | Silent (SNP) | VAF 39/181 reads (22%) | called by muse, mutect2, varscan2
- CDC6 | c.543C>T p.V181= | Silent (SNP) | VAF 68/716 reads (9%) | called by muse, mutect2
- CDKN1A | c.240G>A p.T80= | Silent (SNP) | VAF 98/414 reads (24%) | catalogued as rs984915958, COSV55188066, COSV55191023; called by muse, mutect2, varscan2
- COL12A1 | c.6636T>G p.T2212= | Silent (SNP) | VAF 30/152 reads (20%) | called by muse, mutect2, varscan2
- COL21A1 | c.765A>G p.K255= | Silent (SNP) | VAF 12/142 reads (8%) | catalogued as rs1208744234; called by muse, mutect2
- CPAMD8 | c.5664C>A p.A1888= (on ENST00000651564; = p.A1841= on NM_015692.5) | Silent (SNP) | VAF 115/355 reads (32%) | called by muse, mutect2, varscan2
- DNAH2 | c.10056C>T p.F3352= | Silent (SNP) | VAF 51/193 reads (26%) | catalogued as rs140362383; called by muse, mutect2, varscan2
- ECEL1 | c.1329C>T p.G443= | Silent (SNP) | VAF 81/314 reads (26%) | called by muse, mutect2, varscan2
- EEF1A1 | c.81G>A p.L27= | Silent (SNP) | VAF 42/243 reads (17%) | catalogued as rs1250642922; called by muse, mutect2, varscan2
- EIF5AL1 | c.339T>C p.R113= | Silent (SNP) | VAF 90/430 reads (21%) | catalogued as rs1332714533; called by muse, mutect2, varscan2
- EMX2 | c.444C>T p.N148= | Silent (SNP) | VAF 49/232 reads (21%) | called by mutect2, varscan2
- EPHA3 | c.765C>A p.G255= | Silent (SNP) | VAF 56/291 reads (19%) | called by muse, mutect2, varscan2
- IQUB | c.2271G>T p.V757= | Silent (SNP) | VAF 46/377 reads (12%) | called by muse, mutect2, varscan2
- MAGEA10 | c.819A>G p.Q273= | Silent (SNP) | VAF 82/407 reads (20%) | catalogued as COSV54883133, COSV99726601; called by muse, mutect2, varscan2
- MALRD1 | c.1857G>A p.S619= | Silent (SNP) | VAF 76/228 reads (33%) | catalogued as rs548955209; called by muse, mutect2, varscan2
- MDN1 | c.12597T>G p.S4199= | Silent (SNP) | VAF 66/286 reads (23%) | called by muse, mutect2, varscan2
- MGAM2 | c.3660T>C p.D1220= | Silent (SNP) | VAF 40/259 reads (15%) | catalogued as rs1255809401; called by muse, mutect2, varscan2
- MPO | c.1029C>T p.Y343= | Silent (SNP) | VAF 120/336 reads (36%) | catalogued as rs776941482, COSV56564964; called by muse, mutect2, varscan2
- NCEH1 | c.1149G>T p.L383= (on ENST00000538775; = p.L343= on NM_020792.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 81/358 reads (23%) | called by muse, mutect2, varscan2
- NPAP1 | c.1059A>T p.P353= | Silent (SNP) | VAF 58/221 reads (26%) | called by muse, mutect2, varscan2
- OPRM1 | c.186C>T p.T62= | Silent (SNP) | VAF 84/356 reads (24%) | catalogued as rs1342713581, COSV57674121, COSV57686388; called by muse, mutect2, varscan2
- PCDH8 | c.1038C>T p.D346= | Silent (SNP) | VAF 102/612 reads (17%) | catalogued as rs748227039; called by muse, mutect2, varscan2
- PGAP6 | c.657G>A p.T219= | Silent (SNP) | VAF 71/283 reads (25%) | catalogued as rs375209836; called by muse, mutect2, varscan2
- PNCK | c.120C>T p.L40= (on ENST00000340888 / NM_001366975.1; = p.L123= on NM_001039582.3) | Silent (SNP) | VAF 85/428 reads (20%) | catalogued as rs1345807750, COSV61744665; called by muse, mutect2, varscan2
- PPP1R10 | c.2019C>T p.P673= | Silent (SNP) | VAF 121/457 reads (26%) | catalogued as rs1479479057; called by muse, mutect2, varscan2
- RASGRP3 | c.1026C>T p.S342= | Silent (SNP) | VAF 36/190 reads (19%) | catalogued as rs1234888546; called by muse, mutect2, varscan2
- RTL1 | c.1065G>T p.L355= | Silent (SNP) | VAF 51/215 reads (24%) | called by muse, mutect2, varscan2
- SBK1 | c.789C>T p.F263= | Silent (SNP) | VAF 79/354 reads (22%) | catalogued as rs1194663690, COSV59396709; called by muse, mutect2, varscan2
- SHANK1 | c.2937C>T p.R979= | Silent (SNP) | VAF 83/277 reads (30%) | catalogued as rs774323961; called by muse, mutect2, varscan2
- SLC9A5 | c.2127C>T p.S709= | Silent (SNP) | VAF 56/348 reads (16%) | catalogued as rs746142349; called by muse, varscan2
- SMAD9 | c.573C>G p.P191= | Silent (SNP) | VAF 83/525 reads (16%) | called by muse, mutect2, varscan2
- TNIP3 | c.357G>T p.R119= | Silent (SNP) | VAF 111/181 reads (61%) | called by muse, mutect2, varscan2
- ZFHX3 | c.504G>T p.S168= | Silent (SNP) | VAF 93/452 reads (21%) | catalogued as rs752543837, COSV99214063; called by muse, mutect2, varscan2
- ZNF644 | c.1365G>A p.R455= | Silent (SNP) | VAF 42/206 reads (20%) | catalogued as COSV61346280; called by muse, mutect2, varscan2
- AC010655.3 | n.144C>G | RNA (SNP) | VAF 97/328 reads (30%) | called by muse, mutect2, varscan2
- AL132655.6 | chr20:58839101 C>A | 5'Flank (SNP) | VAF 47/325 reads (14%) | called by muse, mutect2, varscan2
- FBRS | chr16:30662647 A>G | 5'Flank (SNP) | VAF 93/380 reads (24%) | called by muse, mutect2, varscan2
- VMA21 | chrX:151396935 G>A | 5'Flank (SNP) | VAF 77/290 reads (27%) | catalogued as rs1203258433; called by muse, mutect2, varscan2
- XXYLT1 | c.785+34421A>C | Intron (SNP) | VAF 66/179 reads (37%) | called by muse, mutect2, varscan2
